Gene-level copy-number profile of tumor specimen TCGA-61-1728-01A from TCGA case TCGA-61-1728, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 59.1 years (21,582 days).
Specimen TCGA-61-1728-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.aea4673c-80e9-4ef8-a833-cf71ace574a7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-1728-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/35aabe7a-48f1-463f-9eff-8e41f1c483f6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 330; copy number 2: 9,898; copy number 3: 23,295; copy number 4: 18,671; copy number 5: 3,718; copy number 6: 1,113; copy number 7: 914; copy number 8: 550; copy number 9: 568; copy number 10: 152; copy number 11: 180; copy number 13: 84; copy number 15: 7; copy number 16: 125; copy number 17: 18; copy number 18: 24; copy number 19: 37; copy number 20: 126.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-1728-01A-01D-0648-01): tumor purity 0.86, ploidy 3.53, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,785 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–38,198,148, 590 genes, copy number 8–15 (broad region; genes not listed).
- chr5:38,282,264–38,346,551, 2 genes, copy number 9: EGFLAM-AS4, EGFLAM-AS3.
- chr5:40,306,824–45,895,970, 90 genes, copy number 8 (broad region; genes not listed).
- chr8:37,934,281–43,030,535, 121 genes, copy number 9–11 (within-gene range 6–11) (broad region; genes not listed).
- chr8:89,900,721–140,638,283, 694 genes, copy number 7–9 (broad region; genes not listed).
- chr8:141,055,290–145,066,685, 192 genes, copy number 7 (broad region; genes not listed).
- chr11:77,216,558–81,556,425, 59 genes, copy number 10 (within-gene range 5–10): GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1, AP001547.1, MIR708, MIR5579, AP001978.1, AP001541.1, AP001284.1, AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, AP003398.2, AP003464.1, MTND4LP18, MTND6P25.
- chr11:110,788,026–110,788,976, 1 gene, copy number 8: HNRNPA1P60.
- chr11:126,304,060–130,210,362, 55 genes, copy number 8 (within-gene range 3–8): DCPS, GSEC, ST3GAL4, AP001318.3, KIRREL3, KIRREL3-AS1, AP001783.1, AP002833.1, AP002833.3, KIRREL3-AS2, MIR3167, AP002833.2, KIRREL3-AS3, AP001993.1, AP003121.1, LINC02712, RN7SKP121, RN7SKP279, AP003532.1, DNAJB6P1, LINC02725, LINC02098, ETS1, MIR6090, ETS1-AS1, AP001122.1, FLI1, SENCR, KCNJ1, AP000920.1, KCNJ5, C11orf45, TP53AIP1, ARHGAP32, RNU6-876P, Y_RNA, RNU6-874P, ZNF123P, BARX2, RPS27P20, AP003500.1, LINC01395, AP003327.2, AP003327.1, TMEM45B, NFRKB, PRDM10, LINC00167, AP003041.1, ELOBP2, AP003041.2, APLP2, RPL34P21, U4, ST14.
- chr11:130,404,923–130,428,609, 1 gene, copy number 7: ADAMTS8.
- chr11:134,685,044–134,763,810, 3 genes, copy number 7: AP001999.2, LINC02706, LINC02714.
- chr14:18,333,726–20,525,422, 125 genes, copy number 16 (within-gene range 1–16) (broad region; genes not listed).
- chr14:20,955,487–22,482,959, 126 genes, copy number 20 (within-gene range 1–20) (broad region; genes not listed).
- chr19:14,380,501–15,092,970, 37 genes, copy number 19 (within-gene range 6–19): ADGRE5, AC008569.1, DDX39A, PKN1, AC008569.2, PTGER1, GIPC1, SNRPGP15, DNAJB1, TECR, MIR639, NDUFB7, CLEC17A, RN7SL337P, RN7SL842P, ADGRE3, ITGB1P1, AC022149.1, ZNF333, ADGRE2, OR7C1, AC005255.1, OR7A5, OR7A10, OR7A8P, OR7A2P, OR7A17, OR7A18P, OR7A1P, OR7A3P, OR7A11P, OR7A15P, OR7C2, SLC1A6, CCDC105, CASP14, OR1I1.
- chr19:16,572,624–17,075,625, 24 genes, copy number 18: AC008764.8, MED26, AC008764.4, AC008764.7, AC008764.9, AC008764.10, AC008764.2, AC024075.3, SMIM7, AC024075.2, AC024075.1, TMEM38A, AC008737.2, NWD1, AC008737.3, SIN3B, AC008737.1, F2RL3, CPAMD8, RN7SL835P, RN7SL823P, AC020908.2, HAUS8, AC020908.1.
- chr19:21,063,924–22,141,117, 49 genes, copy number 13: VN1R80P, ZNF714, RNA5SP469, VN1R81P, ZNF431, RPL7AP10, VN1R82P, AC010620.1, AC010620.2, RPL36AP51, AC022432.1, VN1R83P, ZNF708, BNIP3P25, ZNF738, AC010615.3, AC010615.1, ZNF493, AC010615.4, AC010615.2, LINC00664, ZNF429, BNIP3P26, AC123912.1, AC123912.4, AC123912.2, AC123912.6, AC123912.5, AC123912.3, MTDHP3, MTDHP4, VN1R84P, ZNF100, CCNYL6, AC092364.1, BRI3BPP1, ZNF43, BNIP3P27, ZNF208, MTDHP2, AC003973.2, BNIP3P28, AC003973.1, ZNF257, BNIP3P29, ZNF92P2, AC073539.2, PCGF7P, MTDHP5.
- chr19:22,902,538–30,713,538, 116 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr20:32,109,714–38,450,940, 218 genes, copy number 7–11 (broad region; genes not listed).
- chr20:38,516,563–38,516,632, 1 gene, copy number 7: MIR548O2.
- chr20:53,255,979–64,242,253, 281 genes, copy number 9–17 (within-gene range 4–17) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 330. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
